Somatic mutation profile of tumor specimen TCGA-EJ-5507-01A (aliquot TCGA-EJ-5507-01A-01D-1576-08) from TCGA case TCGA-EJ-5507, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.1 years (19,759 days).
Specimen TCGA-EJ-5507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd669324-86ea-4978-955c-0cc0540c3e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5507-10A (Blood Derived Normal), aliquot TCGA-EJ-5507-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71f22957-51d7-4fa0-844a-ac6f18a42bb9

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 36/72 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRL3 | c.2681G>A p.R894H (on ENST00000506720 / NM_001322402.2; = p.R826H on NM_015236.6) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs372785017, COSV72230908; called by muse, mutect2, varscan2
- ANKRD13C | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as COSV52031167; called by muse, mutect2
- CACNG4 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1184803592, COSV50924665; called by muse, mutect2, varscan2
- CCDC178 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV55769008; called by muse, mutect2, varscan2
- FER1L5 | c.5821G>A p.E1941K (on ENST00000623019; = p.E1905K on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53841363; called by muse, mutect2
- GLI3 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV67887372, COSV67887596; called by muse, mutect2
- MME | c.1178C>A p.A393D | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV64706844; called by muse, mutect2
- MYBPC1 | c.2663G>A p.R888H (on ENST00000550270 / NM_206820.2; = p.R895H on NM_002465.4) | Missense Mutation (SNP) | VAF 53/463 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs151310085, COSV62253872; called by muse, mutect2, varscan2
- OR5W2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs750353731, COSV60614549, COSV60616410; called by muse, mutect2, varscan2
- PBX1 | c.1013T>G p.F338C | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV63342941; called by muse, mutect2, varscan2
- SCN7A | c.1337C>A p.T446K | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV69270661; called by muse, mutect2, varscan2
- SEZ6L | c.146C>A p.S49* | Nonsense Mutation (SNP) | VAF 34/107 reads (32%) | catalogued as COSV50661295; called by muse, mutect2, varscan2
- SKIV2L | c.1107G>C p.K369N | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64811110; called by muse, mutect2, varscan2
- SNX15 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs771422309, COSV57246500; called by muse, mutect2, varscan2
- SP4 | c.1093C>G p.P365A | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.046); catalogued as COSV56022046; called by muse, mutect2
- SPAG8 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV52413842; called by muse, mutect2, varscan2
- STRIP2 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99973602; called by muse, mutect2, varscan2
- SV2A | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 43/110 reads (39%) | catalogued as rs1266904330, COSV64964417; called by muse, mutect2, varscan2
- SYK | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408106520, COSV65326552, COSV65326829; called by muse, mutect2, varscan2
- TRIP13 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370247932; called by muse, mutect2, varscan2
- USP15 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as COSV54790718; called by muse, mutect2, varscan2
- USP29 | c.665T>C p.L222S | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV54141735; called by muse, mutect2, varscan2
- VILL | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs747938968, COSV52183997; called by muse, mutect2, varscan2
- ZFHX3 | c.8993G>A p.R2998Q | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51715069; called by muse, mutect2, varscan2
- MYEOV | c.504_508del p.F169Sfs*4 | Frame Shift Del (DEL) | VAF 86/395 reads (22%) | called by mutect2, pindel, varscan2
- PPP5C | c.38_48del p.E13Gfs*6 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- DOCK3 | c.2979C>T p.F993= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1223459250, COSV56514848; called by muse, mutect2, varscan2
- EMILIN3 | c.1248C>T p.A416= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as rs768803435, COSV60035761; called by muse, mutect2, varscan2
- NBEAL2 | c.1674A>G p.A558= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV52756513; called by muse, mutect2
- NOTCH4 | c.261C>T p.P87= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1405744691, COSV66682967; called by muse, mutect2
- PIK3CG | c.1959C>T p.D653= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV63247448; called by muse, varscan2
- PKHD1 | c.10866C>T p.C3622= | Silent (SNP) | VAF 63/220 reads (29%) | catalogued as rs562381413, COSV64386429; called by muse, mutect2, varscan2
- SOHLH1 | c.984G>A p.A328= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs776190840, COSV53681264; called by muse, mutect2, varscan2
- TRPM6 | c.618A>G p.G206= | Silent (SNP) | VAF 65/192 reads (34%) | catalogued as COSV62507319; called by muse, mutect2, varscan2
